TCGA case TCGA-QR-A705 — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Heart, mediastinum, and pleura; Tissue source site: National Institutes of Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ebef1483-e3fd-497c-b694-8c3a4e96102f

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Alive.

Diagnoses (3)
1. Extra-adrenal paraganglioma, NOS (the primary disease): ICD-O-3 morphology code: 8693/1; ICD-10 code: C38.0; Tissue or organ of origin: Heart; Site of resection or biopsy: Heart; Classification of tumor: primary; Age at diagnosis: 63.2 years (23,086 days); Year of diagnosis: 2010; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 317 days; Cancer detection method: Screening.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 3.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Carotid body; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 59.6 years (21,778 days); Days to diagnosis: -1,308 days (-3.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.
3. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Carotid body; Laterality: Left; Classification of tumor: Synchronous primary; Age at diagnosis: 59.6 years (21,778 days); Days to diagnosis: -1,308 days (-3.6 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 92 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 317 days; Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QR-A705-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-QR-A705-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QR-A705-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QR-A705-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History pheo or para anatomic site: bilateral carotid body tumors, cardiac, atrial PGL; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: Atrium; Histologic diagnosis: Paraganglioma, Extra-adrenal Pheochromocytoma; Disease detected on screening: Yes; Ct scan preop results: Yes; Lymph nodes examined: Yes.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy histological type: paraganglioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 317 days; disease-specific survival: no event (censored), 317 days; disease-free interval: no event (censored), 317 days; progression-free interval: no event (censored), 317 days.
